Somatic mutation profile of tumor specimen TARGET-30-PASTKW-01A (aliquot TARGET-30-PASTKW-01A-01D) from TARGET case TARGET-30-PASTKW, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of thorax; Age at diagnosis: 2.0 years (716 days).
Specimen TARGET-30-PASTKW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72143263-693e-4a1f-b5cd-4b11da2bc986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASTKW-10A (Blood Derived Normal), aliquot TARGET-30-PASTKW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98310170-0bc3-4dba-958a-d86bad6f5f04

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.5817del p.D1940Ifs*15 | Frame Shift Del (DEL) | VAF 101/530 reads (19%) | catalogued as COSV100969996; called by mutect2, pindel, varscan2
- ATRX | c.4934T>G p.L1645* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as CM002234, COSV64873406; called by muse, mutect2
- DNAH2 | c.10834C>A p.Q3612K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV66717633; called by muse, mutect2, varscan2
- KBTBD8 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.157); catalogued as rs756670732, COSV55127400; called by muse, mutect2
- MED23 | c.3818C>T p.A1273V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.091); catalogued as rs768146584, COSV63431042; called by muse, mutect2, varscan2
- MPO | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV51857428; called by muse, varscan2
- MYOD1 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51452998; called by muse, mutect2, varscan2
- NEDD4L | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56842079; called by muse, mutect2, varscan2
- NUP54 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 40/98 reads (41%) | catalogued as COSV53574843; called by muse, mutect2, varscan2
- PI4KA | c.2972C>A p.S991Y | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55406690; called by muse, mutect2, varscan2
- PXDNL | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV62482234; called by muse, mutect2, varscan2
- RAD54L2 | c.4375G>A p.D1459N | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs936793751; called by muse, mutect2
- TLN1 | c.2534A>G p.E845G | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV59205234; called by muse, mutect2, varscan2
- ABCA5 | c.4897G>C p.E1633Q | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2
- MED14 | c.1197del p.K399Nfs*3 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- PCDH18 | c.2293A>G p.I765V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ARL13B | c.138T>G p.P46= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs755488760, COSV57396915; called by muse, mutect2, varscan2
- ARNTL2 | c.148C>A p.R50= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV53824344, COSV53825144; called by muse, mutect2, varscan2
- SLC26A1 | c.1635G>T p.P545= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV56101974; called by muse, mutect2, varscan2
